Somatic mutation profile of tumor specimen C3N-02598-01 (aliquot CPT0187960007) from CPTAC case C3N-02598, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 60.1 years (21,956 days).
Specimen C3N-02598-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a52d3b3-1fdb-47ad-94b2-d622d181b77e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02598-31 (Blood Derived Normal), aliquot CPT0188020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1546b531-417b-43ab-a8bc-7ed5968950df

The open-access MAF lists 1,468 somatic variants for this specimen: 945 protein-altering or splice-affecting, 371 silent, 152 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 813, Silent 371, Intron 79, Nonsense Mutation 52, Frame Shift Del 35, 3'UTR 23, RNA 19, 5'UTR 18, Splice Site 18, Splice Region 14, Frame Shift Ins 10, 5'Flank 7.

Variants (750 of 1,468; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 84/424 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOE | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 141/606 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs121918395, CM900022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 197/725 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 40/199 reads (20%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- DYNC2H1 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745870321, CM122743, COSV62087131, COSV62095418; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DYRK1A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 50/174 reads (29%) | catalogued as rs724159953, CM1510739, COSV58292386; ClinVar: pathogenic; called by muse, varscan2
- FBXL4 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 32/148 reads (22%) | catalogued as rs964532159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 83/326 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs797045165, CM154919, COSV53145634, COSV53148388; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO5B | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 31/700 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1053713532, CM085575, COSV53215775; ClinVar: pathogenic; called by muse, mutect2
- NDP | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 123/437 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104894878, CM942066, CM950842; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 131/527 reads (25%) | catalogued as rs587778617, CM164326, COSV56224693, COSV99764517; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 122/563 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 56/204 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs587781371, CD136796, COSV52684761, COSV53551526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AATK | c.2146C>T p.R716W (on ENST00000326724 / NM_001080395.3; = p.R613W on NM_004920.2) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1459973620; called by muse, mutect2, varscan2
- ABCA5 | c.128del p.L43Yfs*4 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as rs751512043; called by mutect2, varscan2
- ABO | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 25/234 reads (11%) | catalogued as rs782542998, COSV101505918; called by muse, mutect2, varscan2
- ACCSL | c.1565G>A p.C522Y | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1371529849; called by muse, mutect2, varscan2
- ACOT7 | c.823G>A p.V275M (on ENST00000377855 / NM_181864.3; = p.V265M on NM_007274.4) | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV64112986; called by muse, mutect2, varscan2
- ACOX1 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 79/403 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs369815943; called by muse, mutect2, varscan2
- ACOX2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs375089953; called by muse, mutect2, varscan2
- ACTL7B | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV65927391; called by muse, mutect2, varscan2
- ADAM12 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 143/553 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs572965756, COSV100900300; called by muse, mutect2, varscan2
- ADAMTS17 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1287733938; called by muse, mutect2
- ADCY10 | c.3868G>A p.E1290K | Missense Mutation (SNP) | VAF 168/825 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs571479040; called by muse, mutect2, varscan2
- ADGRA3 | c.3440T>C p.M1147T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs909429953; called by muse, mutect2, varscan2
- AFAP1L1 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs755532054; called by muse, mutect2, varscan2
- AGRN | c.3800C>T p.A1267V | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.122); catalogued as rs760130656; called by muse, mutect2, varscan2
- AK3 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV100729522, COSV63346933; called by muse, mutect2
- AKAP3 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.019); catalogued as rs1220490467, COSV57419479; called by muse, mutect2
- AKAP7 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 54/263 reads (21%) | catalogued as rs145909307; called by muse, mutect2, varscan2
- AL117348.2 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 58/664 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1431697009; called by muse, mutect2
- ALB | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs761118828, COSV55735690; called by muse, mutect2, varscan2
- ALG6 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1287725303, CM098503, COSV99673505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH4 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs765086767, COSV99479642; called by muse, mutect2, varscan2
- AMER2 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as rs780734307; called by mutect2, varscan2
- AMER3 | c.1637dup p.R547Qfs*64 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as rs893863661; called by mutect2, pindel, varscan2
- AMPD1 | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 115/467 reads (25%) | catalogued as rs749286592, COSV62415202; called by muse, mutect2, varscan2
- ANAPC2 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 115/411 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1263721759; called by muse, mutect2, varscan2
- ANKRD27 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.613); catalogued as rs761307804; called by muse, mutect2, varscan2
- AP1G2 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.75); catalogued as rs753591811; called by muse, mutect2, varscan2
- APC2 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757571472, COSV52016391; called by muse, mutect2, varscan2
- APOBR | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs751030621, COSV60494044; called by muse, mutect2
- ARFGEF3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs557172571, COSV99293114; called by muse, mutect2, varscan2
- ARFGEF3 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 87/354 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1467436633, COSV99294350; called by muse, mutect2, varscan2
- ARHGAP29 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 37/178 reads (21%) | catalogued as rs1187150388, COSV53110341; called by muse, mutect2, varscan2
- ARHGAP4 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs200790794; called by muse, mutect2, varscan2
- ARHGEF40 | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs772552739; called by muse, mutect2, varscan2
- ARHGEF6 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 112/402 reads (28%) | catalogued as COSV51691593; called by muse, varscan2
- ARID1A | c.3867-1G>A p.X1289_splice | Splice Site (SNP) | VAF 58/246 reads (24%) | catalogued as COSV61372008; called by muse, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 76/288 reads (26%) | catalogued as rs758608743; called by mutect2, varscan2
- ARMC6 | c.1097G>A p.R366H (on ENST00000392336; = p.R341H on NM_033415.4) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs374945143; called by muse, mutect2, varscan2
- ARNTL | c.1376C>T p.S459F (on ENST00000403290 / NM_001297719.2; = p.S458F on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs750347142; called by muse, mutect2, varscan2
- ARRDC2 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1256936163; called by muse, mutect2, varscan2
- ASB16 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs926461926; called by muse, mutect2, varscan2
- ATG2A | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs560045150; called by muse, mutect2, varscan2
- ATP1A3 | c.379G>A p.D127N (on ENST00000545399 / NM_001256214.2; = p.D114N on NM_152296.5) | Missense Mutation (SNP) | VAF 155/636 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs782128088; called by muse, mutect2, varscan2
- ATP4A | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 155/588 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs769990049, COSV52866484, COSV99382287; called by muse, mutect2, varscan2
- BAHD1 | c.1912C>A p.P638T | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101346814; called by muse, mutect2, varscan2
- BANK1 | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV59839753; called by mutect2, varscan2
- BCL2L1 | c.625C>T p.R209C (on ENST00000307677 / NM_001317919.2; = p.R146C on NM_001191.4) | Missense Mutation (SNP) | VAF 95/417 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs759194807, COSV56966467; called by muse, mutect2, varscan2
- BCL6 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.165); catalogued as rs767642014, COSV51655892; called by muse, mutect2, varscan2
- BCL9 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553204447, COSV99324507, COSV99324562; called by muse, mutect2
- BIRC6 | c.4168C>T p.R1390C | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1335001376, COSV70197450; called by muse, mutect2, varscan2
- BLVRA | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 219/822 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs753216810; called by muse, mutect2, varscan2
- BMP2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 140/489 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1343341933; called by muse, mutect2, varscan2
- BMP2K | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs200678439; called by muse, mutect2, varscan2
- BRAT1 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs546426836, COSV61397574; called by muse, mutect2, varscan2
- BRWD1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs533398417; called by muse, mutect2, varscan2
- BSN | c.8522G>A p.R2841H | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199588705; called by muse, mutect2, varscan2
- BTC | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs782514658, COSV67547635; called by muse, mutect2
- C11orf24 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs147283671; called by muse, mutect2, varscan2
- C16orf96 | c.3088C>T p.R1030C | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs901487393; called by muse, mutect2, varscan2
- C1QL3 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 73/300 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761783743, COSV54348606; called by muse, mutect2, varscan2
- C1QTNF4 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs778095508; called by muse, mutect2, varscan2
- C1orf122 | c.268dup p.Q90Pfs*70 | Frame Shift Ins (INS) | VAF 36/192 reads (19%) | catalogued as rs747134922; called by mutect2, varscan2
- C3 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 151/625 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs752621037; called by muse, mutect2, varscan2
- C9orf78 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV61029602; called by muse, mutect2, varscan2
- CA1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs752181935; called by muse, mutect2, varscan2
- CA2 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.604); catalogued as rs1391649593; called by muse, mutect2, varscan2
- CABIN1 | c.5885C>T p.A1962V | Missense Mutation (SNP) | VAF 92/485 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); catalogued as COSV99574240; called by muse, mutect2, varscan2
- CACNA1B | c.3439G>A p.V1147M | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201232658; called by muse, mutect2, varscan2
- CACNA1C | c.1146G>T p.W382C | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59707729; called by muse, mutect2, varscan2
- CACNB3 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.076); catalogued as rs781195014; called by muse, mutect2, varscan2
- CACNG7 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55817780; called by muse, mutect2, varscan2
- CAMSAP1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1183314481, COSV100410237; called by muse, mutect2, varscan2
- CAMSAP2 | c.3325C>T p.P1109S (on ENST00000236925 / NM_001297707.2; = p.P1098S on NM_203459.3) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1269671236; called by muse, mutect2, varscan2
- CAND2 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1165504138, COSV55989719; called by muse, mutect2, varscan2
- CAPN2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 73/307 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780815282, COSV54334891; called by muse, mutect2, varscan2
- CCDC102A | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs141272360, COSV50777669; called by muse, mutect2, varscan2
- CCDC105 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as COSV99480183; called by muse, mutect2, varscan2
- CCDC106 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 73/389 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.927); catalogued as rs11558497; called by muse, mutect2, varscan2
- CCDC141 | c.2672G>A p.R891Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs775183674, COSV55374672; called by muse, mutect2, varscan2
- CCDC166 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs782218969; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC87 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 110/441 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1228163540; called by muse, mutect2, varscan2
- CCR1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.399); catalogued as rs762847590, COSV56122113; called by muse, mutect2
- CD1C | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 118/493 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.227); catalogued as rs1469611454, COSV63806278; called by muse, mutect2, varscan2
- CDCA7L | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779466315; called by muse, mutect2, varscan2
- CDH4 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64648183; called by muse, mutect2, varscan2
- CDK18 | c.617G>A p.R206Q (on ENST00000506784 / NM_212503.3; = p.R176Q on NM_002596.4) | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs774600930, COSV63727905; called by muse, mutect2, varscan2
- CDK5R1 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 132/476 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1032779285, COSV55578984; called by muse, mutect2, varscan2
- CDON | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs571859031, COSV54995028; called by muse, mutect2, varscan2
- CDR1 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.153); catalogued as COSV65164002, COSV65164723; called by muse, mutect2
- CEACAM16 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs368522084; called by muse, mutect2, varscan2
- CEACAM5 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs782417451; called by muse, mutect2, varscan2
- CELSR1 | c.6541G>A p.A2181T | Missense Mutation (SNP) | VAF 91/380 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.354); catalogued as rs200795497; called by muse, mutect2, varscan2
- CEP57 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 108/374 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs549840259; called by muse, mutect2, varscan2
- CFAP46 | c.1337C>T p.T446M | Missense Mutation (SNP) | VAF 20/608 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1203078672; called by muse, mutect2
- CFAP70 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 46/449 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs918915334; called by muse, mutect2, varscan2
- CHAC1 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 91/342 reads (27%) | catalogued as rs1022667808, COSV71435982; called by muse, mutect2, varscan2
- CHAD | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146207513; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CHD8 | c.4744C>T p.R1582* (on ENST00000646647 / NM_001170629.2; = p.R1303* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 69/331 reads (21%) | catalogued as rs1555314211, COSV63219557; called by muse, mutect2, varscan2
- CHMP7 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs1448264718; called by muse, mutect2, varscan2
- CHRNB1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs779467380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs761599439; called by muse, mutect2, varscan2
- CIITA | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as rs1425490482; called by muse, mutect2, varscan2
- CLCA4 | c.544dup p.I182Nfs*13 | Frame Shift Ins (INS) | VAF 36/188 reads (19%) | catalogued as rs760255767; called by mutect2, varscan2
- CLSTN1 | c.2641C>T p.R881W (on ENST00000377298 / NM_001009566.3; = p.R871W on NM_014944.4) | Missense Mutation (SNP) | VAF 92/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754798318, COSV100740226; called by muse, mutect2, varscan2
- CNTNAP1 | c.2991C>T p.H997= | Splice Region (SNP) | VAF 51/187 reads (27%) | catalogued as rs761083082; called by muse, mutect2, varscan2
- CNTRL | c.6004C>T p.R2002C | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1306400041, COSV53047797; called by muse, mutect2
- COL17A1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 123/463 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs146016251; called by muse, mutect2, varscan2
- COL6A1 | c.895G>T p.G299* | Nonsense Mutation (SNP) | VAF 183/713 reads (26%) | catalogued as CM1310922; called by muse, mutect2, varscan2
- COL6A2 | c.1745G>C p.G582A | Missense Mutation (SNP) | VAF 88/391 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55998715; called by muse, mutect2, varscan2
- COL7A1 | c.8039G>A p.G2680D | Missense Mutation (SNP) | VAF 117/575 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM112251; called by muse, mutect2, varscan2
- COLEC12 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs147145179; called by muse, mutect2, varscan2
- COPB1 | c.2773G>A p.G925S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536084877; called by muse, mutect2, varscan2
- CORO7 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs914281860, COSV52033383; called by muse, mutect2, varscan2
- CRYBG1 | c.5006C>T p.T1669M | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs557753210, COSV64810471; called by muse, mutect2, varscan2
- CS | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 145/601 reads (24%) | catalogued as rs1395257963; called by muse, mutect2, varscan2
- CSMD1 | c.8470A>G p.I2824V (on ENST00000520002; = p.I2823V on NM_033225.6) | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs942842224; called by muse, mutect2, varscan2
- CST1 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100494363, COSV59056122; called by muse, mutect2, varscan2
- CTNNA3 | c.1126C>G p.Q376E | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV65580720; called by muse, mutect2, varscan2
- CUBN | c.4132C>T p.R1378C | Missense Mutation (SNP) | VAF 163/711 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs1290293396, COSV64728057; called by muse, mutect2, varscan2
- CWH43 | c.1656C>T p.H552= | Splice Region (SNP) | VAF 56/172 reads (33%) | catalogued as rs756008708, COSV56942906; called by muse, mutect2, varscan2
- CYHR1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV71324683; called by muse, mutect2, varscan2
- CYP17A1 | c.177del p.K59Nfs*16 | Frame Shift Del (DEL) | VAF 119/484 reads (25%) | catalogued as rs1402132413; called by mutect2, pindel, varscan2
- CYP4V2 | c.1226-1G>A p.X409_splice | Splice Site (SNP) | VAF 324/664 reads (49%) | catalogued as COSV66506806; called by muse, mutect2, varscan2
- DAAM1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs567041153; called by muse, mutect2, varscan2
- DAB2 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 95/400 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs147429919; called by muse, mutect2, varscan2
- DAGLA | c.1859G>A p.C620Y | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.169); catalogued as rs950787400, COSV57199488; called by muse, mutect2, varscan2
- DBF4B | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1394213930; called by muse, mutect2, varscan2
- DCLK2 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs778400715; called by muse, mutect2, varscan2
- DNAAF5 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs200002909, COSV52418060; called by muse, mutect2
- DNAH1 | c.6473C>T p.A2158V | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs775604295, COSV101326486; called by muse, mutect2, varscan2
- DNAH12 | c.9092A>G p.Q3031R (on ENST00000351747; = p.Q3899R on NM_001366028.2) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as COSV61064257; called by muse, varscan2
- DNAH5 | c.13730G>A p.R4577Q | Missense Mutation (SNP) | VAF 53/398 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs759563638, COSV54205926, COSV99447576; called by muse, mutect2, varscan2
- DNAH5 | c.7573G>A p.G2525R | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs771328747, COSV54213772; called by muse, varscan2
- DNAH5 | c.7475C>T p.A2492V | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs529080443, COSV99455587; ClinVar: uncertain significance; called by muse, varscan2
- DNAH7 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs765456809, COSV100415061, COSV100418015; called by muse, mutect2, varscan2
- DNAH8 | c.9398T>A p.I3133N | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100543438; called by muse, mutect2, varscan2
- DNAJC13 | c.5234G>A p.R1745H | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs758169340, COSV53449115; called by muse, mutect2, varscan2
- DNM2 | c.2237C>T p.T746M (on ENST00000355667 / NM_001005360.3; = p.T742M on NM_004945.3) | Missense Mutation (SNP) | VAF 184/735 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs202136528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs200422451, COSV101455492; called by muse, mutect2, varscan2
- DOCK6 | c.4960G>A p.V1654M | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs772437948; called by muse, mutect2, varscan2
- DPP4 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs147146003; called by muse, mutect2, varscan2
- DRC1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs779986198, COSV56534003; called by muse, mutect2, varscan2
- DST | c.21649C>T p.R7217W (on ENST00000361203 / NM_001374722.1; = p.R4914W on NM_015548.5) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210435981, COSV55007682; called by muse, mutect2, varscan2
- DVL1 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 142/671 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.535); catalogued as rs1398232750; called by muse, mutect2, varscan2
- DVL3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs746606032, COSV57455023; called by muse, mutect2, varscan2
- DYRK1A | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1379071994, COSV58294382; called by muse, varscan2
- ECPAS | c.3512G>A p.R1171Q | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543925247; called by muse, mutect2, varscan2
- EEFSEC | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 92/423 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs747582191, COSV54627766; called by muse, mutect2, varscan2
- EIF3B | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs570068196; called by muse, mutect2, varscan2
- EIF3B | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs776923545, COSV100703559; called by muse, mutect2, varscan2
- EP400 | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs924404499, COSV57790698; called by muse, mutect2, varscan2
- EPHA8 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs539448650, COSV51266521; called by muse, mutect2, varscan2
- EPHA8 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs746799254, COSV51274318; called by muse, mutect2
- EPHB2 | c.1979C>T p.T660M (on ENST00000400191 / NM_001309193.2; = p.T661M on NM_004442.7) | Missense Mutation (SNP) | VAF 90/380 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs761101394; called by muse, mutect2, varscan2
- EPPK1 | c.5021G>A p.R1674Q | Missense Mutation (SNP) | VAF 54/629 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as rs546299644; called by muse, mutect2
- ETS1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs753913610; called by muse, varscan2
- ETV5 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV60501449; called by muse, mutect2
- EXPH5 | c.493-1G>A p.X165_splice | Splice Site (SNP) | VAF 38/134 reads (28%) | catalogued as COSV56208783; called by muse, mutect2
- FAM111A | c.81G>A p.P27= | Splice Region (SNP) | VAF 27/127 reads (21%) | catalogued as rs747211416; called by muse, varscan2
- FASN | c.6910G>A p.V2304M | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1007673690; called by muse, mutect2
- FASN | c.5801G>A p.R1934H | Missense Mutation (SNP) | VAF 87/419 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.681); catalogued as rs200897153, COSV60760006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752250876; called by muse, mutect2, varscan2
- FAT2 | c.10376G>C p.G3459A | Missense Mutation (SNP) | VAF 120/546 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745811126, COSV55816485, COSV99941253; called by muse, mutect2, varscan2
- FAT3 | c.12385G>A p.V4129M | Missense Mutation (SNP) | VAF 89/341 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV53135764; called by muse, mutect2, varscan2
- FBXO33 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs942383934; called by muse, mutect2, varscan2
- FBXO41 | c.1613G>A p.S538N | Missense Mutation (SNP) | VAF 52/555 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs541815872; called by muse, mutect2
- FBXW8 | c.1357C>T p.R453C (on ENST00000309909; = p.R491C on NM_012174.1) | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs569559960, COSV59296965; called by muse, mutect2, varscan2
- FCER2 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 39/156 reads (25%) | catalogued as rs752775281, COSV60916414; called by muse, mutect2, varscan2
- FCGBP | c.2914C>T p.R972C | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs772463351; called by muse, mutect2, varscan2
- FCRL5 | c.1009A>G p.R337G | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs746115576; called by muse, mutect2, varscan2
- FCRLB | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as rs1265180340; called by muse, mutect2, varscan2
- FER1L6 | c.1700G>A p.R567K | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.287); catalogued as COSV67548928; called by muse, mutect2, varscan2
- FGF9 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs774141078, COSV66645453, COSV66645564; called by muse, mutect2, varscan2
- FGFBP2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs137933914; called by muse, mutect2, varscan2
- FICD | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 77/348 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as rs542666459; called by muse, mutect2, varscan2
- FKBP10 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 74/369 reads (20%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.582); catalogued as rs781862355, COSV54055016; called by muse, mutect2, varscan2
- FMR1 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 96/448 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs782326789; called by muse, mutect2, varscan2
- FN1 | c.4456+6G>A | Splice Region (SNP) | VAF 52/280 reads (19%) | catalogued as rs1185571861; called by muse, mutect2, varscan2
- FN1 | c.2131G>C p.V711L | Missense Mutation (SNP) | VAF 65/497 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.237); catalogued as COSV60554092; called by muse, mutect2, varscan2
- FOXA1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as rs1410228642; called by muse, mutect2, varscan2
- FOXD4L4 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 64/588 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1357884934; called by mutect2, varscan2
- FOXD4L5 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.692); catalogued as rs1169668258; called by mutect2, varscan2
- FREM2 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV54845650; called by muse, mutect2
- FRMPD4 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 44/160 reads (28%) | catalogued as COSV66212216; called by muse, mutect2, varscan2
- GABBR2 | c.2116G>T p.G706W | Missense Mutation (SNP) | VAF 132/543 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52300277, COSV99410742; called by muse, mutect2, varscan2
- GABBR2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52292077; called by muse, mutect2, varscan2
- GALNT6 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11169818, COSV100695587; called by muse, mutect2, varscan2
- GALNT6 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 138/529 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); catalogued as rs370652722; called by muse, mutect2, varscan2
- GATAD2B | c.992G>T p.R331I | Missense Mutation (SNP) | VAF 108/428 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.272); catalogued as COSV64085142; called by muse, mutect2, varscan2
- GCC1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs765520352, COSV58462142; called by muse, mutect2, varscan2
- GCN1 | c.3946C>T p.R1316* | Nonsense Mutation (SNP) | VAF 94/406 reads (23%) | catalogued as rs1283531605; called by muse, mutect2, varscan2
- GDF15 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs757849452; called by muse, mutect2, varscan2
- GDF5 | c.1240T>C p.W414R | Missense Mutation (SNP) | VAF 108/451 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1312412; called by muse, mutect2, varscan2
- GDF6 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1293581615, COSV99748428; called by muse, mutect2, varscan2
- GEMIN4 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 104/493 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1453616729; called by muse, mutect2, varscan2
- GEMIN4 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 112/494 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs369914416; called by muse, mutect2, varscan2
- GHRH | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1268560247, COSV52902511; called by muse, mutect2, varscan2
- GHRHR | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 156/655 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs1206534113; called by muse, mutect2, varscan2
- GNA11 | c.735+1G>A p.X245_splice | Splice Site (SNP) | VAF 40/144 reads (28%) | catalogued as COSV99313112; called by muse, mutect2, varscan2
- GPM6B | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs761972408; called by muse, mutect2, varscan2
- GPR78 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.145); catalogued as rs773344951, COSV66763501; called by muse, mutect2, varscan2
- GPRIN3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs140623691; called by muse, mutect2, varscan2
- GTF2H4 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV52558221; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1377562943, COSV100736394; called by muse, mutect2, varscan2
- HAPLN1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs374286486, COSV57146076; called by muse, mutect2, varscan2
- HBB | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 129/557 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs35685286, CD951724, CM952029, COSV58941821; ClinVar: other; called by muse, mutect2, varscan2
- HCAR2 | c.923T>C p.L308S | Missense Mutation (SNP) | VAF 51/575 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs748668734; called by muse, mutect2
- HCFC2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57558318; called by muse, mutect2, varscan2
- HDAC10 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1156239816; called by muse, varscan2
- HECTD1 | c.3781C>T p.R1261W | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs761985708, COSV67945554; called by muse, mutect2, varscan2
- HENMT1 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345351239, COSV64230278; called by muse, mutect2, varscan2
- HERC2 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs773677746; called by muse, mutect2
- HKDC1 | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748372161, COSV63575416; called by muse, mutect2, varscan2
- HMGXB3 | c.2914G>A p.V972M (on ENST00000613459; = p.V726M on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/348 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs753841260, COSV72211447; called by muse, mutect2, varscan2
- HNRNPUL1 | c.999G>A p.A333= | Splice Region (SNP) | VAF 58/159 reads (36%) | catalogued as COSV54562029, COSV99647674; called by muse, mutect2, varscan2
- HOXD12 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV66833010; called by muse, mutect2, varscan2
- HRH1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as rs201947424, COSV67955106; called by muse, mutect2, varscan2
- HSPG2 | c.7756C>T p.R2586W | Missense Mutation (SNP) | VAF 125/529 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1199509449; called by muse, mutect2, varscan2
- HTR1A | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 175/725 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100108950, COSV60499859; called by muse, mutect2, varscan2
- HTR2B | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 178/645 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294995476, COSV51448983, COSV51449001; called by muse, mutect2, varscan2
- HYAL1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 122/461 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs782723000; called by muse, mutect2, varscan2
- HYDIN | c.6958C>T p.R2320W | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs138000790, COSV59249098; called by muse, mutect2, varscan2
- IAPP | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs763676184, COSV53713007; called by muse, mutect2, varscan2
- ICAM4 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1248169688; called by muse, mutect2
- IGDCC4 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as COSV61538094; called by muse, mutect2, varscan2
- IGFBP6 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs149870633; called by muse, mutect2, varscan2
- IL17F | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770953888, COSV60235005; called by muse, mutect2, varscan2
- IL5 | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1365792142; called by muse, mutect2, varscan2
- INPP4A | c.2042C>T p.T681M (on ENST00000074304 / NM_001134224.1; = p.T642M on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/394 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746971958; called by muse, mutect2, varscan2
- INPP4A | c.2294G>A p.R765H (on ENST00000074304 / NM_001134224.1; = p.R726H on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50785056; called by muse, mutect2, varscan2
- INPP4A | c.2701C>T p.R901C (on ENST00000074304 / NM_001134224.1; = p.R862C on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99305730; called by muse, mutect2, varscan2
- INPP5F | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs1185907212; called by muse, mutect2, varscan2
- INTS1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1379619477, COSV67176481; called by muse, mutect2, varscan2
- IPPK | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as rs775374177, COSV99845681; called by muse, mutect2, varscan2
- IQGAP2 | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); catalogued as rs375606140; called by muse, mutect2, varscan2
- IQSEC1 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1410621879, COSV56225275; called by muse, mutect2, varscan2
- IRX6 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 126/562 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs904674964, COSV51861676; called by muse, mutect2, varscan2
- ISG20 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 76/314 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs781386863, COSV100044071; called by muse, mutect2, varscan2
- ITGA3 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs762942917; called by muse, mutect2, varscan2
- ITGB4 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 174/735 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751173051; called by muse, mutect2, varscan2
- ITSN2 | c.3820C>T p.R1274W | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766124538; called by muse, mutect2
- JADE2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs370233989; called by muse, mutect2, varscan2
- KANSL1 | c.703A>G p.N235D | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as rs771914337; called by muse, mutect2, varscan2
- KAT6B | c.3409C>T p.R1137C | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373696238, COSV54746312; called by muse, mutect2, varscan2
- KAT6B | c.5242G>A p.V1748I | Missense Mutation (SNP) | VAF 94/421 reads (22%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.168); catalogued as rs774598396, COSV54745257; called by muse, mutect2, varscan2
- KCNC1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1180139307; called by muse, mutect2
- KCND1 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 40/179 reads (22%) | catalogued as rs781783068, COSV99502158; called by muse, mutect2, varscan2
- KCNH6 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 114/416 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1370937590; called by muse, mutect2, varscan2
- KCNS1 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60260502; called by muse, mutect2, varscan2
- KHNYN | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750247971, COSV99249977; called by muse, mutect2, varscan2
- KIF13A | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52449004, COSV52454731; called by muse, mutect2, varscan2
- KIF26B | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199690740; called by muse, mutect2, varscan2
- KIF7 | c.3031C>T p.R1011C | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757590116, COSV51538975; called by muse, mutect2
- KMT2D | c.15815C>T p.A5272V | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV56423223, COSV56464782; called by muse, mutect2, varscan2
- KMT2D | c.8074C>T p.R2692W | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771966959, COSV56413162; called by muse, mutect2, varscan2
- KNL1 | c.5377G>C p.E1793Q (on ENST00000346991 / NM_170589.5; = p.E1767Q on NM_144508.5) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs1170663121, COSV61153654; called by muse, mutect2, varscan2
- LAMA2 | c.9014C>T p.A3005V | Missense Mutation (SNP) | VAF 116/443 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs75048006, COSV70343885; called by muse, mutect2, varscan2
- LAMA5 | c.10994T>C p.M3665T | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs199962785; called by muse, mutect2, varscan2
- LIMA1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs756628778; called by muse, mutect2, varscan2
- LLGL2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs780370026; called by muse, mutect2, varscan2
- LOXL2 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs770656880; called by muse, mutect2, varscan2
- LOXL2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 145/582 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs143787010; called by muse, mutect2, varscan2
- LRBA | c.4297del p.S1433Vfs*14 | Frame Shift Del (DEL) | VAF 50/143 reads (35%) | catalogued as COSV63949190; called by mutect2, pindel, varscan2
- LRGUK | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as rs762700582; called by muse, mutect2, varscan2
- LRP1B | c.10916G>A p.C3639Y | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1021055992; called by muse, mutect2, varscan2
- LRP8 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs75360028; called by muse, mutect2, varscan2
- LSP1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 85/409 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs772024277; called by muse, mutect2, varscan2
- LVRN | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 68/281 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63496173; called by muse, mutect2, varscan2
- LYPD2 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 91/338 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs766307085, COSV63649396, COSV63649517; called by muse, mutect2, varscan2
- MAGEA11 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.034); catalogued as rs1557362254; called by muse, mutect2, varscan2
- MAGEB18 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 47/412 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV57464268; called by muse, mutect2, varscan2
- MAGED2 | c.1570G>A p.G524R | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1453457173; called by muse, mutect2, varscan2
- MAGEL2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated, low confidence (0.1); catalogued as rs1216919340, COSV58568327; called by muse, mutect2, varscan2
- MAN2B1 | c.2864C>T p.T955M | Missense Mutation (SNP) | VAF 96/409 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs771210668; called by muse, mutect2, varscan2
- MAN2B2 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs147138092; called by muse, mutect2, varscan2
- MAP3K11 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs201727045, COSV58418152; called by muse, mutect2, varscan2
- MAP3K3 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.083); catalogued as rs747980360; called by muse, mutect2, varscan2
- MAPK8IP3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1238541918; called by muse, mutect2, varscan2
- MAPKAPK2 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782749899; called by muse, mutect2, varscan2
- MAPT | c.2345C>T p.A782V (on ENST00000262410 / NM_001377265.1; = p.A390V on NM_005910.5) | Missense Mutation (SNP) | VAF 156/615 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762104961; called by muse, mutect2, varscan2
- MARF1 | c.4117C>A p.R1373S | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60027983; called by muse, mutect2, varscan2
- MARK3 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 97/425 reads (23%) | catalogued as rs763214749, COSV53509356; called by muse, mutect2, varscan2
- MAT1A | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 210/869 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs377184051, COSV64745164; called by muse, mutect2, varscan2
- MATN3 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs775138248; called by muse, mutect2, varscan2
- MAVS | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 95/357 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV63926494; called by muse, mutect2, varscan2
- MCAM | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 98/367 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.75); catalogued as rs753858877, COSV50679751; called by muse, mutect2, varscan2
- MCHR1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 61/435 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.442); catalogued as rs199641758, COSV50762679; called by muse, mutect2, varscan2
- MDGA1 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs756958252, COSV51800005; called by muse, mutect2, varscan2
- MECP2 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 210/810 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.062); catalogued as rs1034253564; called by muse, mutect2, varscan2
- MEGF11 | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 86/455 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs757871149, COSV99988776; called by muse, mutect2, varscan2
- METTL14 | c.1302C>G p.F434L | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.878); catalogued as COSV66310236; called by muse, mutect2, varscan2
- MFGE8 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 192/728 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs772448343; called by muse, mutect2, varscan2
- MFN2 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 152/616 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as rs28940296, CM041389; called by muse, mutect2, varscan2
- MKRN3 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as rs750269411; called by muse, mutect2, varscan2
- MMP25 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs376635558; called by muse, mutect2, varscan2
- MRGPRX3 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs148026500; called by muse, mutect2, varscan2
- MSANTD1 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs746030094; called by muse, mutect2
- MSH6 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 129/637 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs376220212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC12 | c.16258C>T p.R5420* (on ENST00000379442; = p.R5277* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 49/269 reads (18%) | catalogued as rs890519288; called by muse, mutect2, varscan2
- MUC16 | c.41807G>A p.R13936H | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.988); catalogued as rs772257744, COSV101110047; called by muse, mutect2, varscan2
- MUC16 | c.9131C>T p.S3044F | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs777674896; called by muse, mutect2, varscan2
- MUC4 | c.11320G>A p.A3774T | Missense Mutation (SNP) | VAF 90/746 reads (12%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.086); catalogued as rs1288568337, COSV57796828; called by muse, varscan2
- MVK | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 197/804 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104895363, CM062890; ClinVar: not provided; called by muse, varscan2
- MYH8 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 121/452 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161189464, COSV67967763; called by muse, mutect2, varscan2
- MYH9 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 58/784 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53381778; called by muse, mutect2
- MYLIP | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs774445093, COSV62766827; called by muse, mutect2, varscan2
- MYLK3 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 22/319 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs764891090; called by muse, mutect2
- MYO3A | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 92/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200209381, COSV56330720, COSV56338173; called by muse, mutect2, varscan2
- MYO9B | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201903372; called by muse, mutect2, varscan2
- MYOD1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 100/317 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV51454218; called by muse, mutect2, varscan2
- MYORG | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.096); catalogued as rs1431959498; called by muse, mutect2, varscan2
- MYPN | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 124/507 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs145923914; called by muse, mutect2, varscan2
- NAV3 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs759179498, COSV57060090; called by muse, mutect2, varscan2
- NBR1 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs372269996; called by muse, mutect2, varscan2
- NCAPD2 | c.3661C>T p.R1221W | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370458466, COSV99975469; called by muse, mutect2, varscan2
- NCKIPSD | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 78/405 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs139058555; called by muse, mutect2, varscan2
- NCOA5 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs6074011, COSV51642328; called by muse, mutect2, varscan2
- NDRG2 | c.1040G>A p.R347H (on ENST00000298687 / NM_001354570.1; = p.R333H on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.997); catalogued as rs750366803; called by muse, mutect2, varscan2
- NECTIN2 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754949827, COSV99374977; called by muse, mutect2, varscan2
- NF1 | c.2835del p.F945Lfs*9 | Frame Shift Del (DEL) | VAF 80/273 reads (29%) | catalogued as rs1567849208; called by mutect2, pindel, varscan2
- NHLRC1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 103/440 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.306); catalogued as CM150709, COSV100513506; called by muse, mutect2, varscan2
- NHSL1 | c.3779C>T p.T1260M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.316); catalogued as rs995390765; called by muse, mutect2, varscan2
- NID2 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99356062; called by muse, mutect2, varscan2
- NKX6-3 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.195); catalogued as rs550795574; called by muse, mutect2, varscan2
- NOL6 | c.3083C>T p.S1028L | Missense Mutation (SNP) | VAF 106/444 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1284399566; called by muse, varscan2
- NOMO1 | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1420968429, COSV99814820; called by muse, mutect2
- NONO | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs757029715; called by muse, mutect2, varscan2
- NOP14 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748092379; called by muse, mutect2, varscan2
- NPEPPS | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179179896; called by muse, mutect2, varscan2
- NPHS1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 102/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs190112072, COSV104422304; called by muse, mutect2, varscan2
- NPIPB4 | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 148/1244 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs534531061; called by muse, varscan2
- NRG1 | c.215C>T p.A72V (on ENST00000523534; = p.A219V on NM_013962.2) | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs754569262, COSV101585021; called by muse, varscan2
- NRXN1 | c.4228G>A p.A1410T | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs764870690, COSV60515075; called by muse, mutect2, varscan2
- NSA2 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs769700489; called by muse, mutect2, varscan2
- NSMCE1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1444560834, COSV63863949; called by muse, mutect2, varscan2
- NT5M | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs773032923; called by muse, mutect2, varscan2
- NTRK1 | c.2201C>T p.T734M | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs755323716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 40/154 reads (26%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- OAS3 | c.1501C>T p.R501* | Nonsense Mutation (SNP) | VAF 143/629 reads (23%) | catalogued as rs1299900361, COSV57443763; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs762005098; called by mutect2, pindel
- OPN5 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs780695747, COSV99054545; called by muse, mutect2, varscan2
- OR2H1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as rs973562412; called by muse, mutect2, varscan2
- OR51B5 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 44/162 reads (27%) | catalogued as rs112127098; called by muse, mutect2, varscan2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 159/709 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2, varscan2
- OR52I2 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs146669514; called by muse, mutect2, varscan2
- OR52K1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 105/446 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs552943528, COSV56903135; called by muse, mutect2, varscan2
- OR7D4 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs112089905, COSV58071510; called by muse, mutect2, varscan2
- ORC3 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs781229815; called by muse, mutect2, varscan2
- OSBPL2 | c.275C>T p.T92M (on ENST00000313733 / NM_144498.4; = p.T80M on NM_014835.4) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs994772771, COSV58216485; called by muse, mutect2
- OSBPL7 | c.1120-4A>G | Splice Region (SNP) | VAF 64/227 reads (28%) | catalogued as rs1401964319; called by muse, mutect2, varscan2
- OXER1 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 112/527 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as COSV54313330; called by muse, mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 25/280 reads (9%) | catalogued as rs753912794; called by mutect2, pindel
- P3H1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 51/436 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52531762; called by muse, mutect2, varscan2
- PCDHA10 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 169/695 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV100253389; called by muse, mutect2, varscan2
- PCDHA12 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 31/874 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV56551323; called by muse, mutect2
- PCDHA2 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 110/483 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs781801031, COSV65365129, COSV65367572; called by muse, mutect2, varscan2
- PCDHA9 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 138/681 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs782817644, COSV65326881; called by muse, mutect2, varscan2
- PCDHGA12 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as rs767521224, COSV52741799; called by muse, mutect2, varscan2
- PCDHGA5 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 17/562 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV53944010; called by muse, mutect2
- PCDHGA7 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 81/396 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99542641; called by muse, mutect2, varscan2
- PCDHGB2 | c.2146C>T p.R716* | Nonsense Mutation (SNP) | VAF 129/646 reads (20%) | catalogued as COSV53938344, COSV54040289; called by muse, mutect2, varscan2
- PCLO | c.10452G>A p.M3484I | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100427551; called by muse, mutect2, varscan2
- PCLO | c.4901A>G p.D1634G | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1173307645, COSV61670210; called by muse, mutect2
- PCNT | c.7334C>T p.A2445V | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs749868653, COSV64028022; called by muse, mutect2, varscan2
- PCNT | c.7681C>T p.R2561C | Missense Mutation (SNP) | VAF 101/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs751345838; called by muse, mutect2, varscan2
- PCNX1 | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1266233073, COSV53102276; called by muse, mutect2, varscan2
- PDHA1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 154/614 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs768396832, COSV100870322; ClinVar: likely benign; called by muse, varscan2
- PDIA3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200051575, COSV55855970; called by muse, mutect2, varscan2
- PDZD2 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 88/350 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs765814114, COSV56850789; called by muse, mutect2, varscan2
- PEDS1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59014001; called by muse, mutect2
- PEG10 | c.499G>A p.A167T (on ENST00000482108 / NM_001040152.2; = p.A201T on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV71788054, COSV71788659; called by muse, mutect2, varscan2
- PHF1 | c.1214G>A p.R405Q (on ENST00000374516 / NM_024165.3; = p.A401= on NM_002636.5) | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as rs772352148; called by muse, mutect2, varscan2
- PHLDB1 | c.3827G>A p.R1276H | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782415248, COSV61881741; called by muse, mutect2, varscan2
- PHRF1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs375767361; called by muse, mutect2, varscan2
- PHYKPL | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 97/399 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.812); catalogued as rs780234084, COSV100069511; called by muse, mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 28/120 reads (23%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PKD1L1 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 130/493 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs745425347, COSV99219013; called by muse, mutect2, varscan2
- PLCB3 | c.2827G>A p.A943T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs1238246666; called by muse, mutect2, varscan2
- PLEKHG2 | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as rs374850282; called by muse, mutect2, varscan2
- PLEKHH2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs146823531; called by muse, mutect2, varscan2
- POLE | c.3475C>T p.P1159S | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57677478; called by muse, mutect2
- POLRMT | c.2987C>T p.T996M | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477199080; called by muse, mutect2, varscan2
- POPDC2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs564285845; called by muse, mutect2
- POU3F4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as rs777196693; called by muse, mutect2, varscan2
- PPIL2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.195); catalogued as rs1238902791; called by muse, mutect2, varscan2
- PPP1R13B | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.599); catalogued as rs752636119; called by muse, mutect2, varscan2
- PPP1R16A | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs750255812, COSV99477515; called by muse, mutect2, varscan2
- PRDM15 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs749891082; called by muse, mutect2, varscan2
- PREB | c.661G>C p.V221L | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs1191425938; called by muse, mutect2, varscan2
- PREX1 | c.2267G>A p.G756D | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1384353174, COSV64253438; called by muse, mutect2, varscan2
- PRICKLE2 | c.2566C>T p.R856C (on ENST00000295902; = p.R800C on NM_198859.4) | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as COSV55766064; called by muse, mutect2, varscan2
- PRKCA | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs755962439, COSV52577701; called by muse, mutect2, varscan2
- PRLR | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs759313604, COSV51498371, COSV51499443; called by muse, mutect2, varscan2
- PRODH | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.592); catalogued as rs1321845990, COSV104396028; called by mutect2, varscan2
- PROSER3 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 37/183 reads (20%) | catalogued as rs767350506; called by muse, mutect2, varscan2
- PSMD9 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 69/381 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs1360811934; called by muse, mutect2, varscan2
- PTEN | c.676del p.S226Pfs*30 | Frame Shift Del (DEL) | VAF 88/376 reads (23%) | catalogued as COSV64305880; called by mutect2, pindel, varscan2
- PTGIR | c.768G>A p.T256= | Splice Region (SNP) | VAF 20/88 reads (23%) | catalogued as rs757009606; called by muse, mutect2, varscan2
- PTP4A1 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs546134768, COSV65715431; called by muse, mutect2, varscan2
- PTPMT1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs201520358; called by muse, mutect2, varscan2
- PTPN18 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 116/496 reads (23%) | catalogued as rs1393936540; called by muse, mutect2, varscan2
- PTPN23 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs148327878; called by muse, mutect2, varscan2
- PYGB | c.999+1G>T p.X333_splice | Splice Site (SNP) | VAF 38/149 reads (26%) | catalogued as rs775476799; called by muse, mutect2
- RANGRF | c.438-6C>A | Splice Region (SNP) | VAF 131/341 reads (38%) | catalogued as rs1351095415; called by muse, mutect2, varscan2
- RARA | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54192452; called by muse, mutect2, varscan2
- RBBP6 | c.3757C>T p.R1253* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as COSV60508116; called by muse, mutect2, varscan2
- RBM15B | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs781873510; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 46/226 reads (20%) | catalogued as rs762006287; called by mutect2, varscan2
- RBMXL3 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782729732; called by muse, mutect2, varscan2
- RBP3 | c.119G>A p.C40Y | Missense Mutation (SNP) | VAF 68/874 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1565763618; called by muse, mutect2
- RBPJL | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs911393889, COSV59213109; called by muse, mutect2
- RESF1 | c.3994C>T p.R1332C | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs538266903; called by muse, mutect2, varscan2
- RGS1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV66505258; called by muse, mutect2, varscan2
- RGS3 | c.650G>A p.R217H (on ENST00000350696 / NM_001282923.2; = p.R105H on NM_017790.4) | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752898002, COSV104398417, COSV58280679; called by muse, mutect2, varscan2
- RHBDL2 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs139113067; called by muse, mutect2, varscan2
- RHBDL3 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1033222442; called by muse, mutect2
- RIN1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 21/595 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs995530676; called by muse, mutect2
- RIPK3 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs369990803; called by muse, mutect2, varscan2
- RMI1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs768068417; called by muse, mutect2, varscan2
- RNF31 | c.1336dup p.R446Pfs*21 | Frame Shift Ins (INS) | VAF 29/167 reads (17%) | catalogued as rs758350558; called by mutect2, pindel, varscan2
- RNF31 | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758763901; called by muse, mutect2, varscan2
- RNF32 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 97/320 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); catalogued as rs1389511127; called by muse, mutect2, varscan2
- RNF34 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.16); catalogued as rs781869526, COSV63443519; called by muse, mutect2, varscan2
- RP1L1 | c.6682G>A p.V2228I | Missense Mutation (SNP) | VAF 182/708 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.2); catalogued as rs780986691, COSV66761848; called by muse, varscan2
- RS1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs61753171, CM981762, COSV66106075; ClinVar: not provided; called by muse, mutect2, varscan2
- RSF1 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs374557189, COSV100406811; called by muse, mutect2, varscan2
- RSPH1 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 98/365 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs374702500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUBCN | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 12/395 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1262994691, COSV56364390; called by muse, mutect2
- RUNDC3B | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs563701368, COSV99712220; called by muse, mutect2, varscan2
- RUNX1T1 | c.598G>A p.A200T (on ENST00000265814 / NM_001198628.1; = p.A173T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs766588136, COSV56140268, COSV56144015; called by muse, mutect2, varscan2
- RXYLT1 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs528696188; called by muse, mutect2, varscan2
- RYR3 | c.8722G>A p.A2908T (on ENST00000389232; = p.A2909T on NM_001036.6) | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs557377918; called by muse, mutect2, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 27/115 reads (23%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCAI | c.1378G>A p.A460T (on ENST00000336505 / NM_001144877.3; = p.A483T on NM_173690.5) | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100332667; called by muse, mutect2, varscan2
- SCML4 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 26/124 reads (21%) | catalogued as rs959901101, COSV64634431; called by muse, mutect2, varscan2
- SCN9A | c.2330C>T p.A777V (on ENST00000303354; = p.A766V on NM_002977.3) | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs749482425; called by muse, mutect2
- SEC16A | c.4238G>A p.S1413N | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV51529809; called by muse, mutect2, varscan2
- SEL1L3 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs773292219, COSV53535780, COSV99340924; called by muse, mutect2, varscan2
- SEMA5B | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs747653179, COSV99533607; called by muse, mutect2, varscan2
- SETD2 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs935586454, COSV57437115; called by muse, mutect2, varscan2
- SETD3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745547818, COSV59286748; called by muse, mutect2, varscan2
- SFMBT1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750697192; called by muse, mutect2, varscan2
- SFSWAP | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1296866923, COSV55519468; called by muse, mutect2
- SFTPC | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1000316822, COSV59345309; called by muse, mutect2, varscan2
- SH2B2 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782512441; called by muse, mutect2, varscan2
- SH3RF3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 118/477 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as rs1200435927, COSV58695711; called by muse, mutect2, varscan2
- SHC2 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 109/523 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757191912, COSV99199261; called by muse, mutect2, varscan2
- SIPA1L3 | c.4631C>T p.S1544L | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs771877025, COSV55912576; called by muse, mutect2
- SLAIN2 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs774856780, COSV51906703; called by muse, mutect2, varscan2
- SLC11A1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs371489451; called by muse, mutect2, varscan2
- SLC13A2 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); catalogued as rs782617929, COSV100120026; called by muse, mutect2, varscan2
- SLC18A3 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1417056757, COSV60325575; called by muse, mutect2, varscan2
- SLC25A26 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs767197019; called by muse, mutect2, varscan2
- SLC27A1 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs866732455; called by muse, mutect2, varscan2
- SLC27A3 | c.2209G>A p.V737M (on ENST00000271857; = p.V609M on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs374422194; called by muse, mutect2, varscan2
- SLC29A1 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.228); catalogued as rs889640597; called by muse, mutect2, varscan2
- SLC35A2 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 106/400 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs939923485; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC45A2 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs142175557; ClinVar: uncertain significance; called by muse, mutect2
- SLC46A3 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); catalogued as COSV57181840; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC4A5 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.253); catalogued as rs557733369, COSV61030035; called by muse, varscan2
- SLC6A16 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs534129369; called by muse, mutect2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | catalogued as rs747319777; called by mutect2, varscan2
- SLITRK4 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 66/250 reads (26%) | catalogued as rs868985356; called by muse, mutect2, varscan2
- SMO | c.901A>G p.M301V | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs754444361; called by muse, mutect2, varscan2
- SNX17 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1350040005, COSV52011894; called by muse, mutect2, varscan2
- SPATA31D1 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs569655832, COSV61193279; called by muse, mutect2, varscan2
- SPATA9 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as COSV57224701; called by muse, mutect2, varscan2
- SPEG | c.3730C>T p.R1244C | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs770645696; called by muse, mutect2, varscan2
- SPTBN1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61688416; called by muse, mutect2, varscan2
- SPTBN1 | c.4294C>T p.R1432W | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs878981910; called by muse, mutect2, varscan2
- SRC | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 118/444 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV62441269; called by muse, mutect2, varscan2
- SRCIN1 | c.2648C>T p.T883M (on ENST00000621492; = p.T849M on NM_025248.3) | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs767903662; called by muse, mutect2, varscan2
- SREBF2 | c.2092G>A p.V698M | Missense Mutation (SNP) | VAF 178/833 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758318118, COSV63333156; called by muse, mutect2, varscan2
- SRGAP1 | c.2816C>T p.T939M | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.047); catalogued as rs1186421658, COSV61900862; called by muse, mutect2, varscan2
- SSMEM1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 74/377 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1404413432, COSV52832942, COSV99927706; called by muse, mutect2, varscan2
- ST14 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs781073815, COSV53834334, COSV99074081; called by muse, mutect2, varscan2
- ST3GAL3 | c.520C>T p.R174C (on ENST00000361392 / NM_174964.4; = p.R159C on NM_006279.5) | Missense Mutation (SNP) | VAF 114/441 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1558784546, COSV99495296; called by muse, mutect2, varscan2
- ST8SIA3 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 136/860 reads (16%) | PolyPhen benign (0.141); catalogued as COSV60653630; called by muse, mutect2, varscan2
- STARD6 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs768682509, COSV57141939; called by muse, mutect2
- STK10 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs753084325; called by muse, mutect2, varscan2
- STK38L | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779567614; called by muse, mutect2
- STRIP1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1186518003; called by muse, mutect2, varscan2
- SUDS3 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1185298509, COSV64348796; called by muse, mutect2, varscan2
- SUSD5 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1370987627, COSV100535031; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYDE1 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.478); catalogued as rs1351918764, COSV54620103; called by muse, mutect2
- SYMPK | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs555466334; called by muse, mutect2, varscan2
- SYNM | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV100152444; called by muse, mutect2, varscan2
- TAS2R5 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774459669, COSV99924848; called by muse, mutect2, varscan2
- TAT | c.706+4C>T | Splice Region (SNP) | VAF 108/473 reads (23%) | catalogued as rs756665631; called by muse, mutect2, varscan2
- TBC1D14 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs374685226, COSV68985597; called by muse, mutect2
- TBCD | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183349235, COSV62807732; called by muse, mutect2, varscan2
- TBKBP1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.384); catalogued as rs538496762; called by muse, mutect2, varscan2
- TCEA3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs906613658; called by muse, mutect2, varscan2
- TCFL5 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 153/617 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs775014868; called by muse, mutect2, varscan2
- TCP1 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV58458177; called by muse, mutect2, varscan2
- TEDC2 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV53539895; called by muse, mutect2, varscan2
- TEP1 | c.4051C>T p.R1351* | Nonsense Mutation (SNP) | VAF 77/284 reads (27%) | catalogued as rs148696839; called by muse, mutect2, varscan2
- TEP1 | c.3481G>A p.G1161R | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1304450572, COSV52995806; called by muse, mutect2, varscan2
- THBS2 | c.3164C>T p.T1055M | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs1350658095; called by muse, mutect2
- THNSL2 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 156/622 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1282073698; called by muse, mutect2, varscan2
- TIGD3 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs142471374; called by muse, mutect2, varscan2
- TMCC2 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 107/467 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.166); catalogued as rs910160085, COSV58006170; called by muse, mutect2, varscan2
- TMCC2 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 41/395 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs375049317; called by muse, mutect2, varscan2
- TMED1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV53035352; called by muse, mutect2, varscan2
- TMEM109 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 107/454 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs369970045; called by muse, mutect2, varscan2
- TMEM121 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1555444366; called by muse, varscan2
- TMEM132C | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV70668040; called by muse, mutect2, varscan2
- TMEM186 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs755239323, COSV51632569; called by muse, mutect2, varscan2
- TMEM35A | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 81/357 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54502368; called by muse, mutect2, varscan2
- TMEM98 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758327656; called by muse, mutect2, varscan2
- TMX2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759161110; called by muse, mutect2
- TNFAIP3 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 96/451 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs536079833, COSV52796472; called by muse, mutect2, varscan2
- TNPO1 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61524543; called by muse, mutect2, varscan2
- TNPO2 | c.2305+2T>C p.X769_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100790441; called by muse, mutect2, varscan2
- TNRC18 | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs533389149; called by muse, mutect2, varscan2
- TRERF1 | c.2789C>T p.T930M | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769282713; called by muse, mutect2, varscan2
- TRIM29 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 111/416 reads (27%) | catalogued as rs1273863461, COSV59280042; called by muse, mutect2, varscan2
- TRIM3 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV61984202; called by muse, mutect2, varscan2
- TRIM41 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as rs752692102; called by muse, mutect2, varscan2
- TRIM45 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374186718; called by muse, mutect2, varscan2
- TRMT2A | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 69/442 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs142476770; called by muse, mutect2, varscan2
- TRPC5 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1010020042, COSV53291712; called by muse, mutect2, varscan2
- TRPM1 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 13/398 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56632151; called by muse, mutect2
- TRPM5 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1001851644; called by muse, mutect2, varscan2
- TSC22D2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV62622237; called by muse, mutect2, varscan2
- TTC12 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 17/484 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs559449784, COSV100133305; called by muse, mutect2
- TTLL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 41/190 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as rs1225806777; called by muse, mutect2, varscan2
- TUBA3C | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); catalogued as rs371896594, COSV101262761; called by muse, mutect2
- TUBE1 | c.746del p.K249Sfs*10 | Frame Shift Del (DEL) | VAF 40/219 reads (18%) | catalogued as rs1554315980; called by mutect2, pindel, varscan2
- TYW1 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs141862060; called by muse, mutect2, varscan2
- UBE2NL | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 135/531 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs150007003; called by muse, mutect2, varscan2
- UNK | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1264339563, COSV104394339; called by muse, mutect2, varscan2
- USP24 | c.5638G>A p.V1880I | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs780083902, COSV53766105, COSV53770881; called by muse, mutect2
- UTP20 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99882370; called by muse, mutect2, varscan2
- VPS35L | c.2551G>A p.G851R | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529462508, COSV51985706; called by muse, mutect2, varscan2
- VWA5A | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as rs1175064642; called by muse, mutect2, varscan2
- VWA5B2 | c.2710C>T p.R904* | Nonsense Mutation (SNP) | VAF 42/114 reads (37%) | catalogued as rs1021369623; called by muse, mutect2, varscan2
- VWDE | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 61/291 reads (21%) | catalogued as rs1367919010; called by muse, mutect2, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 26/153 reads (17%) | catalogued as rs756173793; called by mutect2, varscan2
- WDR13 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs782003747; called by muse, mutect2, varscan2
- WDR27 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs770155454, COSV61216520; called by muse, mutect2, varscan2
- WDR46 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs750599381; called by muse, mutect2, varscan2
- WDR90 | c.3704G>T p.W1235L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99552642; called by muse, mutect2, varscan2
- WDTC1 | c.1091G>A p.R364H (on ENST00000319394 / NM_001276252.2; = p.R363H on NM_015023.5) | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs149286456; called by muse, mutect2, varscan2
- WTIP | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs375329839; called by muse, mutect2, varscan2
- XKR4 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs931462398, COSV59311222; called by muse, mutect2
- ZBED9 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs998813719; called by muse, mutect2, varscan2
- ZFHX3 | c.4315C>T p.R1439* | Nonsense Mutation (SNP) | VAF 72/328 reads (22%) | catalogued as COSV51729171; called by muse, mutect2, varscan2
- ZKSCAN5 | c.875A>G p.Q292R | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.094); catalogued as rs181655073; called by muse, mutect2, varscan2
- ZMAT4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as rs144919411, COSV52701716, COSV52713141; called by muse, mutect2, varscan2
- ZMYM5 | c.1747A>C p.T583P | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); catalogued as rs957509458; called by muse, mutect2, varscan2
- ZNF205 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 113/428 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54621874; called by muse, mutect2, varscan2
- ZNF251 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs376486971, COSV52959293; called by muse, mutect2, varscan2
- ZNF3 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); catalogued as rs774181879, COSV52795980; called by muse, mutect2, varscan2
- ZNF415 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs373210709; called by muse, mutect2
- ZNF423 | c.2546C>T p.T849M (on ENST00000563137 / NM_001379286.1; = p.T841M on NM_015069.4) | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as rs375710152; called by muse, mutect2, varscan2
- ZNF462 | c.4981C>T p.R1661W | Missense Mutation (SNP) | VAF 85/371 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775693844; called by muse, mutect2, varscan2
- ZNF483 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 88/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs770409913; called by muse, mutect2, varscan2
- ZNF506 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV71354322; called by muse, mutect2, varscan2
- ZNF521 | c.3166G>A p.G1056R | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.896); catalogued as COSV64127778; called by muse, mutect2
- ZNF526 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 210/782 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs757513094; called by muse, mutect2, varscan2
- ZNF541 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as rs751903947, COSV54542902; called by muse, mutect2, varscan2
- ZNF554 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs373131556; called by muse, mutect2, varscan2
- ZNF672 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 78/347 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.132); catalogued as COSV60637480; called by muse, mutect2, varscan2
- ZNF689 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54907955; called by muse, mutect2
- ZNF813 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 90/370 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs375351117, COSV67177068; called by muse, mutect2, varscan2
- ZXDB | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1490879691; called by muse, mutect2, varscan2
- ABCC8 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD17B | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACP7 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACTN1 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ACVR2B | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 167/696 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ADAP2 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAT1 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCK5 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 53/637 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRB1 | c.622A>T p.I208F | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AFF2 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 29/332 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.038); called by muse, mutect2
- AGO2 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ALDH1A2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 15/523 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALG11 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD33B | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 112/418 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD35 | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ANO4 | c.1970A>C p.K657T (on ENST00000392977 / NM_001286615.2; = p.K622T on NM_178826.4) | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APBA1 | c.1422C>G p.D474E | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- APLF | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AQP9 | c.203T>A p.V68D | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ARHGAP19 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ARHGAP45 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ARHGEF12 | c.1152T>G p.H384Q | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARNT | c.1502C>A p.P501H | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ARSI | c.917del p.G306Afs*21 | Frame Shift Del (DEL) | VAF 56/227 reads (25%) | called by mutect2, pindel, varscan2
- ART5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ATG4D | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ATG9B | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ATP1B2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ATP8B1 | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 224/832 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP9B | c.2264T>A p.L755Q | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATXN7 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B4GALNT4 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- BANK1 | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- BCOR | c.3283C>A p.P1095T | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCR | c.2060G>A p.S687N | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- BEND3 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BRINP1 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BTBD16 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- C1orf185 | c.71T>A p.I24N | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2orf50 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, varscan2
- CACNG5 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 56/195 reads (29%) | called by muse, mutect2, varscan2
- CARD8 | c.673C>A p.H225N (on ENST00000651546 / NM_001184900.3; = p.H175N on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 157/627 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CCDC124 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CCDC18 | c.3644C>T p.A1215V (on ENST00000343253 / NM_001306076.1; = p.A1216V on NM_206886.4) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CCDC93 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CCT8 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDHR5 | c.2407C>T p.P803S (on ENST00000358353 / NM_001171968.2; = p.P809S on NM_021924.5) | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDIP1 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDK3 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2
- CENPI | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CEPT1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 21/539 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CER1 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); called by muse, mutect2
- CFAP20DC | c.1016C>T p.A339V (on ENST00000482387 / NM_001351530.2; = p.A214V on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CHD3 | c.2960A>G p.E987G | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHI3L2 | c.851C>G p.A284G | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CHRM2 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 152/573 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNTNAP3 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 119/474 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL11A1 | c.2559T>C p.G853= | Splice Region (SNP) | VAF 64/306 reads (21%) | called by muse, mutect2, varscan2
- COL14A1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.26); called by muse, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 42/309 reads (14%) | called by mutect2, pindel, varscan2
- CRB1 | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CROCC | c.4118C>T p.A1373V | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRY2 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 28/363 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- CRYBG2 | c.764G>T p.R255M | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSMD2 | c.10156C>T p.Q3386* | Nonsense Mutation (SNP) | VAF 90/365 reads (25%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2
- CTTN | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CYB5R3 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 24/437 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2
- CYLD | c.2636G>T p.G879V | Missense Mutation (SNP) | VAF 184/757 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP7B1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 90/434 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYSRT1 | c.513del p.F172Sfs*84 (on ENST00000409414; = p.F132Sfs*84 on NM_199001.5) | Frame Shift Del (DEL) | VAF 118/497 reads (24%) | called by mutect2, pindel, varscan2
- DACH1 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DACT3 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DAPK1 | c.1786C>A p.L596I | Missense Mutation (SNP) | VAF 109/461 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DAZAP1 | c.436T>G p.Y146D | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHRS7C | c.791G>A p.R264H (on ENST00000330255 / NM_001220493.2; = p.R263H on NM_001105571.3) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- DHX9 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- DISP1 | c.1101T>A p.C367* | Nonsense Mutation (SNP) | VAF 55/255 reads (22%) | called by muse, mutect2, varscan2
- DLK1 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 56/391 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DNAJC10 | c.868G>T p.G290* | Nonsense Mutation (SNP) | VAF 43/244 reads (18%) | called by muse, mutect2, varscan2
- DNAJC11 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DOP1A | c.4189A>G p.I1397V | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- DST | c.2575C>T p.Q859* (on ENST00000361203 / NM_001374722.1; = p.Q533* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- EBF3 | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EBF4 | c.929del p.P310Rfs*10 (on ENST00000609451; = p.P306Rfs*10 on NM_001110514.1) | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- EGLN2 | c.841A>T p.K281* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | called by muse, varscan2
- EIF2AK4 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- EIF2B4 | c.418+1G>A p.X140_splice (on ENST00000347454 / NM_001034116.2; = p.X139_splice on NM_015636.3) | Splice Site (SNP) | VAF 92/373 reads (25%) | called by muse, mutect2, varscan2
- EP400 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EPHB1 | c.1553G>A p.S518N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ESF1 | c.280del p.I94* | Frame Shift Del (DEL) | VAF 57/229 reads (25%) | called by mutect2, pindel, varscan2
- ETFB | c.58-8C>A | Splice Region (SNP) | VAF 35/343 reads (10%) | called by muse, mutect2, varscan2
- EYS | c.2967C>A p.N989K | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM71F2 | c.71del p.N24Mfs*7 | Frame Shift Del (DEL) | VAF 73/328 reads (22%) | called by mutect2, pindel, varscan2
- FANCD2 | c.3323A>G p.E1108G | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FBN2 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- FBXL5 | c.103del p.S35Pfs*62 | Frame Shift Del (DEL) | VAF 27/130 reads (21%) | called by mutect2, pindel
- FCHSD2 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FERD3L | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- FGD5 | c.3743G>A p.C1248Y | Missense Mutation (SNP) | VAF 68/475 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGF23 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 17/560 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- FHOD3 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- FIZ1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- FOXD1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- FOXD1 | c.326_328del p.A109del | In Frame Del (DEL) | VAF 12/73 reads (16%) | called by mutect2*, varscan2
- FZD8 | c.354C>A p.C118* | Nonsense Mutation (SNP) | VAF 43/365 reads (12%) | called by muse, mutect2, varscan2
- GAB3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 140/575 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- GEMIN5 | c.4277del p.N1426Mfs*9 | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- GIMAP6 | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2
- GRIA1 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 128/575 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GTF3C1 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 99/417 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- H3C12 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HAS1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- HCAR3 | c.923T>C p.L308S | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.776); called by muse, mutect2
- HCN4 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 89/432 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIVEP3 | c.5312A>G p.K1771R | Missense Mutation (SNP) | VAF 161/692 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HK3 | c.2060G>A p.G687D | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA10 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- HOXD12 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 51/577 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.357); called by muse, mutect2
- HSPA4L | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTT | c.6778C>A p.L2260M | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ICAM5 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IFT122 | c.1504G>C p.V502L (on ENST00000348417 / NM_052989.3; = p.V443L on NM_018262.4) | Missense Mutation (SNP) | VAF 83/448 reads (19%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGLV2-33 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 74/416 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IGSF22 | c.2566G>T p.G856C (on ENST00000319338; = p.G957C on NM_173588.4) | Missense Mutation (SNP) | VAF 158/628 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- IL17C | c.101dup p.H35Tfs*6 | Frame Shift Ins (INS) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- IL17RE | c.1763T>C p.L588P | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IL3RA | c.806C>A p.T269K | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, varscan2
- IMPACT | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INPP4B | c.1182-2A>G p.X394_splice | Splice Site (SNP) | VAF 130/253 reads (51%) | called by muse, mutect2, varscan2
- INPP5A | c.829-1G>T p.X277_splice | Splice Site (SNP) | VAF 30/258 reads (12%) | called by muse, varscan2
- INSRR | c.2542A>G p.K848E | Missense Mutation (SNP) | VAF 95/326 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- IPO8 | c.640-1G>A p.X214_splice | Splice Site (SNP) | VAF 63/218 reads (29%) | called by muse, mutect2, varscan2
- IRX1 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ITGB2 | c.2054C>T p.T685I (on ENST00000302347; = p.T661I on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/671 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGBL1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT6A | c.4760G>A p.C1587Y | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNA3 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDELR2 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2
- KDM4B | c.1681T>C p.W561R | Missense Mutation (SNP) | VAF 32/479 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.519); called by muse, mutect2
- KDM4B | c.2279G>A p.C760Y | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM6A | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 79/570 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIAA0232 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KIAA0232 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.306); called by muse, mutect2
- KIAA0408 | c.1967C>A p.P656Q | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA0825 | c.3395G>A p.C1132Y | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1217 | c.4186T>C p.S1396P | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KIAA1755 | c.3589C>A p.L1197I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KIF1C | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL10 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 110/394 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KRBA1 | c.1709G>A p.S570N | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LAMA2 | c.4397G>A p.C1466Y | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB2 | c.955C>A p.L319I | Missense Mutation (SNP) | VAF 134/752 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- LAMC3 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 107/451 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LATS2 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LDB1 | c.994A>C p.S332R (on ENST00000425280 / NM_001321612.2; = p.S296R on NM_003893.5) | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2
- LMOD1 | c.1581del p.G529Vfs*22 | Frame Shift Del (DEL) | VAF 56/226 reads (25%) | called by mutect2, pindel, varscan2
- LRIT3 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 153/268 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LRP2 | c.12790A>G p.R4264G | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- LRRIQ1 | c.2744G>A p.C915Y | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEB1 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- MAGEE2 | c.1138C>A p.L380I | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MAP7D1 | c.2007G>T p.Q669H | Missense Mutation (SNP) | VAF 92/435 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MB21D2 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 123/490 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
718 further variants in this file (195 protein-altering or splice-affecting, 371 silent, 152 other) are not listed here.
